Somatic mutation profile of tumor specimen TCGA-4X-A9FD-01A (aliquot TCGA-4X-A9FD-01A-11D-A423-09) from TCGA case TCGA-4X-A9FD, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 43.7 years (15,968 days).
Specimen TCGA-4X-A9FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee93041c-6963-4e68-864a-49425039bace.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4X-A9FD-10A (Blood Derived Normal), aliquot TCGA-4X-A9FD-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3abac96-57ff-42f0-a8e2-d66232900204

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXF1 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM135697; called by muse, mutect2, varscan2
- GALNT14 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs760329260; called by muse, mutect2, varscan2
- NLRC5 | c.4018G>T p.V1340L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV52660983; called by muse, mutect2, varscan2
- PHKA2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1319135942, COSV66056024; called by muse, mutect2, varscan2
- RHPN1 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs758787319, COSV56648837; called by mutect2, varscan2
- URI1 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780661066; called by muse, mutect2, varscan2
- ZNF318 | c.3622C>A p.P1208T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV104401877; called by muse, mutect2, varscan2
- CLDN5 | c.214G>A p.A72T (on ENST00000618236 / NM_001363066.2; = p.A157T on NM_003277.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- CNTNAP4 | c.3239A>G p.Y1080C | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL1 | c.8796_8797del p.K2932Nfs*5 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel, varscan2
- DOCK2 | c.4187A>T p.D1396V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- FMOD | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2
- IFT140 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- KAT6A | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); called by muse, varscan2
- MUC5B | c.13301C>T p.T4434I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PCDHA4 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SLC44A1 | c.1016T>G p.F339C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- BPIFB1 | c.237C>T p.T79= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs370901362; called by muse, mutect2, varscan2
- RAD54L | c.292T>C p.L98= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs1204468479; called by muse, mutect2, varscan2
- TNR | c.468C>T p.N156= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs765569785, COSV54901502; called by muse, mutect2, varscan2
